Somatic mutation profile of tumor specimen MP2PRT-PATZCB-TMP1-A (aliquot MP2PRT-PATZCB-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATZCB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,488 days).
Specimen MP2PRT-PATZCB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53204f9b-6572-46ad-a139-488e21caedc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZCB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZCB-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc2e0a9-294f-4f52-8b85-035863f7ed3f

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- G6PC | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- IGHV1-58 | c.349_350delinsAGAGGGGGGCA p.A117delinsRGGQ | In Frame Ins (INS) | VAF 6/32 reads (19%) | called by pindel, varscan2*
- LRIG3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBA2 | c.1284_1285insGG p.L429Gfs*23 | Frame Shift Ins (INS) | VAF 110/317 reads (35%) | called by mutect2, pindel*, varscan2
- IGHV1-58 | c.321C>T p.S107= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs911072372; called by muse, varscan2
- PPL | c.576C>T p.S192= | Silent (SNP) | VAF 147/352 reads (42%) | catalogued as rs759052273, COSV62045971; called by muse, mutect2, varscan2
- SCN10A | c.2973G>A p.P991= | Silent (SNP) | VAF 143/349 reads (41%) | catalogued as rs201397469; ClinVar: likely benign; called by muse, mutect2, varscan2
